Somatic mutation profile of tumor specimen ALCH-AE92-TTP1-A (aliquot ALCH-AE92-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE92, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 78.5 years (28,673 days).
Specimen ALCH-AE92-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad264368-dfd4-4d98-8e56-7d586bc5faf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE92-NB1-A (Blood Derived Normal), aliquot ALCH-AE92-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a50215a-4987-4e6b-8c43-084fbfb4d54c

The open-access MAF lists 66 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Nonsense Mutation 5, Splice Site 4, Intron 4, 5'UTR 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 150/1128 reads (13%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 58/469 reads (12%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CELSR2 | c.4951G>A p.G1651S | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as rs201428256; called by muse, mutect2, varscan2
- CNOT7 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs767567772; called by muse, mutect2
- COL9A1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 29/492 reads (6%) | catalogued as rs147237457; called by muse, mutect2
- DSCAM | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as rs752670424, COSV68022860; called by muse, mutect2
- EIF2AK3 | c.911C>G p.A304G | Missense Mutation (SNP) | VAF 66/780 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57553153; called by muse, mutect2
- FEZ1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.98); catalogued as COSV99057052; called by muse, mutect2
- MAGEB2 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 43/490 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100975607; called by muse, mutect2
- MGAT5 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 28/499 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as rs1260252204; called by muse, mutect2
- MKI67 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs764041173, COSV100896911, COSV64073095; called by muse, mutect2
- OR51S1 | c.61T>G p.L21V | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV100437554; called by muse, mutect2
- PCDH15 | c.2752G>T p.D918Y | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57266468; called by muse, mutect2
- TMCO3 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64807405; called by muse, mutect2
- VPS37D | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs782436225; called by muse, mutect2
- ZNF319 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 27/200 reads (14%) | catalogued as rs1350267249; called by muse, mutect2, varscan2
- ZNF470 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs762515924; called by muse, mutect2, varscan2
- ADAMTS17 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ARMC3 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2
- CNTN2 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2
- EPHA5 | c.2763C>A p.S921R | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.503); called by muse, mutect2
- GSPT2 | c.1516G>T p.G506* | Nonsense Mutation (SNP) | VAF 36/339 reads (11%) | called by muse, mutect2, varscan2
- HERC5 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- INSYN2B | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 32/499 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- LAMC1 | c.4770G>T p.E1590D | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- MAGEL2 | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MFN1 | c.744T>G p.Y248* | Nonsense Mutation (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- MPPED2 | c.721A>T p.R241W | Missense Mutation (SNP) | VAF 39/526 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- MX1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 21/256 reads (8%) | called by muse, mutect2
- NOL10 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCARE | c.1161C>A p.H387Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCDH11X | c.2427C>A p.D809E | Missense Mutation (SNP) | VAF 62/874 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); called by muse, mutect2
- PGPEP1 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 46/405 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHF3 | c.4981C>T p.P1661S | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- RNF17 | c.3611-3_3612delinsTTGTT p.X1204_splice | Splice Site (ONP) | VAF 10/111 reads (9%) | called by mutect2*, pindel
- SLC47A1 | c.606C>G p.N202K | Missense Mutation (SNP) | VAF 41/579 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SSX1 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- TNRC6B | c.3802A>T p.M1268L (on ENST00000454349 / NM_001162501.2; = p.M1158L on NM_015088.3) | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- TTC8 | c.1273-1G>C p.X425_splice (on ENST00000338104 / NM_001288781.1; = p.X409_splice on NM_144596.4) | Splice Site (SNP) | VAF 87/1113 reads (8%) | called by muse, mutect2
- ZBTB21 | c.2402A>T p.N801I | Missense Mutation (SNP) | VAF 52/696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF536 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZP4 | c.1161-2A>G p.X387_splice | Splice Site (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- CACNA2D1 | c.432G>A p.R144= | Silent (SNP) | VAF 56/813 reads (7%) | called by muse, mutect2
- CYP1A1 | c.540G>T p.G180= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs201933340; called by muse, mutect2
- DCBLD1 | c.906C>T p.G302= | Silent (SNP) | VAF 50/687 reads (7%) | catalogued as rs375609762; called by muse, mutect2
- DOCK6 | c.3291C>T p.F1097= | Silent (SNP) | VAF 26/222 reads (12%) | catalogued as rs774204294; called by muse, mutect2, varscan2
- EPHA5 | c.2574C>G p.A858= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as COSV56673737; called by muse, mutect2
- FAM234A | c.1521C>A p.G507= | Silent (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- GDF6 | c.180G>T p.A60= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- LRP4 | c.3615C>T p.L1205= | Silent (SNP) | VAF 44/610 reads (7%) | called by muse, mutect2
- MAK | c.1254C>G p.S418= | Silent (SNP) | VAF 36/468 reads (8%) | called by muse, mutect2
- NUP43 | c.351A>G p.T117= | Silent (SNP) | VAF 11/285 reads (4%) | called by muse, mutect2
- PFKP | c.993C>T p.I331= | Silent (SNP) | VAF 22/452 reads (5%) | catalogued as rs755284709; called by muse, mutect2
- PPP1R3F | c.1596C>T p.R532= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as rs1023008960; called by muse, mutect2
- PROSER1 | c.1632C>G p.P544= | Silent (SNP) | VAF 60/670 reads (9%) | called by muse, mutect2
- RAD50 | c.1752A>G p.S584= | Silent (SNP) | VAF 40/446 reads (9%) | catalogued as rs786203790; ClinVar: likely benign; called by muse, mutect2
- TUBAL3 | c.1086C>T p.I362= | Silent (SNP) | VAF 30/255 reads (12%) | catalogued as rs1554813754; called by muse, mutect2, varscan2
- CEP89 | c.667+14G>A | Intron (SNP) | VAF 33/547 reads (6%) | called by muse, mutect2
- CHODL | c.-1G>A | 5'UTR (SNP) | VAF 19/338 reads (6%) | catalogued as rs1166644122; called by muse, mutect2
- LCT | c.986+28C>T | Intron (SNP) | VAF 40/466 reads (9%) | called by muse, mutect2
- OPRM1 | c.-267G>T | 5'UTR (SNP) | VAF 18/196 reads (9%) | catalogued as COSV57687887; called by muse, mutect2
- SSPOP | n.7787G>T | RNA (SNP) | VAF 20/172 reads (12%) | catalogued as COSV65133847; called by muse, mutect2, varscan2
- SSTR5-AS1 | n.574G>A | RNA (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- SUFU | c.1296+1688G>A | Intron (SNP) | VAF 32/280 reads (11%) | catalogued as rs1420244522; called by muse, mutect2, varscan2
- TNPO1 | c.-21C>G | 5'UTR (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2
- TYK2 | c.2047+484A>G | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
